Somatic mutation profile of tumor specimen TCGA-KT-A74X-01A (aliquot TCGA-KT-A74X-01A-11D-A32B-08) from TCGA case TCGA-KT-A74X, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 26.3 years (9,590 days).
Specimen TCGA-KT-A74X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3106ba01-5eef-4149-924e-770a6bfed766.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KT-A74X-10A (Blood Derived Normal), aliquot TCGA-KT-A74X-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6d156f4-bad4-48d2-9c7f-5981054a418d

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 37/50 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1380826096, COSV50546987; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1392_1403del p.D464_Y467del (on ENST00000521381 / NM_181523.3; = p.D194_Y197del on NM_181504.4) | In Frame Del (DEL) | VAF 14/43 reads (33%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- HSD17B8 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as rs1302985247, COSV100761818; called by muse, mutect2
- LMO1 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs536636517, COSV59959097; called by muse, mutect2, varscan2
- SLC26A8 | c.215G>A p.C72Y | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV100839559; called by muse, mutect2, varscan2
- ADGRF2 | c.594T>C p.I198= (on ENST00000296862 / NM_001368115.2; = p.I130= on NM_153839.7) | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as rs750989231, COSV99731522; called by muse, mutect2, varscan2
- CNOT4 | c.1692A>G p.G564= (on ENST00000315544 / NM_001190848.1; = p.G561= on NM_001008225.2) | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV100211963; called by muse, mutect2, varscan2
- PUS7 | c.81T>C p.V27= | Silent (SNP) | VAF 54/110 reads (49%) | catalogued as COSV100708602; called by muse, mutect2, varscan2
- SATL1 | c.417G>A p.R139= (on ENST00000395409; = p.R326= on NM_001012980.2) | Silent (SNP) | VAF 29/37 reads (78%) | catalogued as COSV100261007; called by muse, mutect2, varscan2
